MMRF case MMRF_2567 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/413f58e8-677c-4776-b5f2-c68912dccbf9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.7 years (22,917 days); ISS stage: II; Days to last known disease status: 626 days (1.7 years); Days to last follow up: 626 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 180 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 189 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 179 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 211 days; Days to treatment end: 212 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 214 days; Days to treatment end: 214 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 295 days; Days to treatment end: 343 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 295 days; Days to treatment end: 344 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 295 days; Days to treatment end: 352 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 407 days (1.1 years); Days to treatment end: 438 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 407 days (1.1 years); Days to treatment end: 443 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 4.88 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.701 mg/dL; Immunoglobulin G 59.5 g/L; Immunoglobulin A 0.189 g/L; Immunoglobulin M 0.322 g/L; Beta 2 Microglobulin 2.86 µg/mL; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.76 ×10⁹/L; Absolute Neutrophil 2.49 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 90.2 µmol/L; Albumin 31 g/L; Total Protein 10.9 g/dL; C-Reactive Protein 0.17 mg/dL.
- Day 80 (ECOG 0): M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.817 mg/dL; Immunoglobulin G 7.11 g/L; Immunoglobulin A 0.831 g/L; Immunoglobulin M 0.514 g/L; Lactate Dehydrogenase 5.03 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 12.9 ×10⁹/L; Absolute Neutrophil 11.3 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL.
- Day 169 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.856 mg/dL; Immunoglobulin G 3.76 g/L; Immunoglobulin A 0.511 g/L; Immunoglobulin M 0.418 g/L; Lactate Dehydrogenase 5 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.19 ×10⁹/L; Absolute Neutrophil 2.15 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 93.7 µmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL.
- Day 274 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.569 mg/dL; Immunoglobulin G 3.51 g/L; Immunoglobulin A 0.439 g/L; Immunoglobulin M 0.278 g/L; Lactate Dehydrogenase 5.43 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.86 ×10⁹/L; Absolute Neutrophil 5.08 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 88.4 µmol/L.
- Day 343 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.853 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.627 mg/dL; Immunoglobulin G 3.47 g/L; Immunoglobulin A 0.336 g/L; Immunoglobulin M 0.512 g/L; Beta 2 Microglobulin 2.04 µg/mL; Lactate Dehydrogenase 6.75 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.74 ×10⁹/L; Absolute Neutrophil 5.48 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 91.1 µmol/L; Calcium 2.18 mmol/L; Albumin 44 g/L; Total Protein 6 g/dL.
- Day 443 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.737 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.535 mg/dL; Immunoglobulin G 2.93 g/L; Immunoglobulin A 0.437 g/L; Immunoglobulin M 0.304 g/L; Lactate Dehydrogenase 5.05 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 2.28 ×10⁹/L; Absolute Neutrophil 1.33 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 83.1 µmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL.
- Day 626 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.754 mg/dL; Immunoglobulin G 4.83 g/L; Immunoglobulin A 0.816 g/L; Immunoglobulin M 0.277 g/L; Lactate Dehydrogenase 5.72 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 82.2 µmol/L; Glucose 6.66 mmol/L.

Other clinical attributes
- Day -6: Weight: 97 kg; Height: 181 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2567_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2567_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
